FM case AD16206 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/1ce30511-94d8-4105-b46b-7144ddb0d425

Male, 33.9 years: Carcinoma, NOS (ICD-O-3 8010/3) of the major salivary gland; primary biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
